Surgical pathology report (de-identified scan), TCGA case TCGA-24-1847, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Washington University, specimen TCGA-24-1847-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT
FINAL

DIAGNOSIS:

OVARIES, BILATERAL, SIMPLE OOPHORECTOMY

- HIGH GRADE SEROUS ADENOCARCINOMA
- EXTENSIVE LYMPHVASCULAR SPACE INVASION BY ADENOCARCINOMA

FALLOPIAN TUBES, BILATERAL, SALPINGO-OOPHORECTOMY

- METASTATIC HIGH GRADE SEROUS ADENOCARCINOMA
- EXTENSIVE LYMPHVASCULAR SPACE INVASION BY ADENOCARCINOMA

UTERUS, CERVIX, PROCEDURE NOT STATED

- METASTATIC HIGH GRADE SEROUS ADENOCARCINOMA IN PERICERVICAL SOFT TISSUE
- EXTENSIVE LYMPHVASCULAR SPACE INVASION BY ADENOCARCINOMA

UTERUS, ENDOMETRIUM, PROCEDURE NOT STATED

- PROLIFERATIVE ENDOMETRIUM WITH FOCAL BREAKDOWN
- BENIGN ENDOMETRIAL POLYP

UTERUS, MYOMETRIUM, PROCEDURE NOT STATED

- EXTENSIVE LYMPHVASCULAR SPACE INVASION BY ADENOCARCINOMA
- LEIOMYOMA

PERITONEUM, BLADDER, BIOPSY

- METASTATIC HIGH GRADE SEROUS ADENOCARCINOMA

OMENTUM, EXCISION

- METASTATIC HIGH GRADE SEROUS ADENOCARCINOMA

By this signature, I attest that the above diagnosis is based upon my personal examination of the slides (and/or other material indicated in the diagnosis).

***Report Electronically Reviewed and Signed Out By

Microscopic Description and Comment:

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

Microscopic examination substantiates the above cited diagnosis.

History:

The patient is a [REDACTED] with stage IV Mullerian carcinoma. Operative procedure: Not stated.

Specimen(s) Received:

A: BLADDER PERITONEUM

B: UTERUS, CERVIX, BILATERAL TUBES AND OVARIES

C: OMENTUM

Gross Description:

The specimens are received in three formalin-filled containers, each labeled [REDACTED]. The first container is labeled "bladder peritoneum." It contains two firm pieces of soft tissue, one of which is brown-black, measuring 3 x 0.9 x 0.3 cm in greatest dimension; the other is tan-yellow-and-brown, measuring 3.7 x 1 x 0.5 cm in greatest dimension.

The second container is labeled [REDACTED]. It contains a uterus and cervix, and two detached fallopian tubes and ovaries. The uterus and cervix measure 6 cm from cornu-to-cornu, 10 cm from cervix-to-fundus, and 6.2 cm from anterior-to-posterior. Approximately 25% of the cervix has been previously removed from the anterior half. The uterus is opened to show a flattened endometrial polyp within a triangular endometrial cavity. The endometrial polyp measures 2.2 x 1.5 cm. The endometrial cavity measures 3 x 3. The endocervical canal is unremarkable and measures 2.5 cm in length and 0.5 cm in diameter. The remaining cervix and ectocervix are tan-white and unremarkable. A single intramural fibroid, with a tan-white and whorled cut surface, is identified and measures 1 cm in greatest dimension. There are two ovaries with attached fallopian tubes also identified within the container. The smaller of the two has a fallopian tube with a paratubal cyst; the fallopian tube measures 3 cm in length and 0.8 cm in diameter, with a paratubal cyst that measures 1.3 cm; next to the paratubal cyst is a tan-white and firm area that measures 0.9 cm in greatest dimension; at the medial end of the fallopian tube (nearest the uterus) is a tan-white and tan-yellow firm mass that is attached to the paratubal soft tissue and measures 2.2 x 2.2 cm in greatest dimension; this mass may represent the ovary. The larger specimen has a somewhat serpiginous but unremarkable fallopian tube that measures 3.5 cm in length and 1 cm in diameter; a cystic and firm mass/ovary is attached to the paratubal soft tissue and measures 5.5 x 3.5 x 2.5 cm in greatest dimension; sectioning the mass shows a cystic tan-yellow and golden lesion with a trabeculated lining without papillary excrescences; no normal ovarian stroma is identified. Labeled B1 and B2 - anterior and posterior cervix; B3 and B4 - anterior and posterior endocervix; B5 and B6 - anterior and posterior endometrium with polyp (in both); B7 - smaller fallopian tube with paratubal cyst; B8 and B9 - smaller mass/ovary; B10 - larger fallopian tube; B11 to B16 - larger mass/ovary; B17 - leiomyoma from uterus. [REDACTED]

The third container is labeled "omentum." It contains a section of unremarkable fibroadipose tissue/omentum that measures 43.5 x 10.5 x 1.5 cm. Sectioning shows multiple tan-white well-circumscribed nodules that are consistent with metastatic disease, ranging in size from 0.2 to 0.8 cm in greatest dimension. Labeled C1 and C2 - sections of firm nodules. [REDACTED]

Source: NCI Genomic Data Commons file 95d522e8-92ce-4fcc-a5ec-18c0f2d89d6b (TCGA-24-1847.20D96D45-40D3-44AD-A9E8-FDC7E545ED5D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).